CCDI case PBCMRF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/12d1207c-4aef-4ce1-ae06-3d363becaf30

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Biospecimens (3 samples)
- Sample 0DVPN3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVPOR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVPP5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
